MMRF case MMRF_2515 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9c028615-f909-42c9-9dc3-602f424e4730

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 87 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 87.1 years (31,810 days); ISS stage: I; Days to last known disease status: 687 days (1.9 years); Days to last follow up: 687 days (1.9 years).
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 33 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 2): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 44.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 225 mg/dL; Immunoglobulin G 18.8 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 4.98 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 7.9 g/dL; C-Reactive Protein 0.19 mg/dL.
- Day 75 (ECOG 2): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 170 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.45 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 16.1 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 5.06 mmol/L.
- Day 161 (ECOG 2): M Protein 0.22 g/dL; Immunoglobulin G 8.9 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.19 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.79 mmol/L.
- Day 266 (ECOG 2): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 67.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 98.5 mg/dL; Immunoglobulin G 6.35 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 2.67 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 71.6 µmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 5.17 mmol/L.
- Day 329 (ECOG 2): M Protein 0.13 g/dL; Immunoglobulin G 6.55 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.1 µg/mL; Hemoglobin 7.25 mmol/L; Leukocytes 3.35 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 4.62 mmol/L.
- Day 448 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 5.05 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.79 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 82 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 4.51 mmol/L.
- Day 526 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 5.55 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.57 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 4.18 mmol/L.
- Day 687 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 6.61 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.77 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.31 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -13: Weight: 49 kg; Height: 144 cm.

Biospecimens (2 samples)
- Sample MMRF_2515_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_2515_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
